Somatic mutation profile of tumor specimen C3L-06983-55 (aliquot CPT0408640002) from CPTAC case C3L-06983, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 61.9 years (22,623 days).
Specimen C3L-06983-55: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af670111-e2f0-435a-bc27-a20d4be00f23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06983-50 (Buccal Cell Normal), aliquot CPT0408610001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d2f352e-3735-48d5-9a28-77f64e86f063

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC42 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.306); catalogued as rs766057119, COSV53449785; called by muse, mutect2
- NR5A2 | c.1330G>A p.D444N (on ENST00000367362 / NM_205860.3; = p.D398N on NM_003822.5) | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52660360; called by muse, mutect2, varscan2
- ZNF292 | c.5719C>T p.Q1907* | Nonsense Mutation (SNP) | VAF 12/144 reads (8%) | catalogued as rs868869031; called by muse, mutect2
